Somatic mutation profile of tumor specimen TCGA-GJ-A6C0-01A (aliquot TCGA-GJ-A6C0-01A-12D-A30V-10) from TCGA case TCGA-GJ-A6C0, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 75.6 years (27,626 days).
Specimen TCGA-GJ-A6C0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77f5e14d-e76d-4574-bc1d-2de769ea6ce1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GJ-A6C0-10A (Blood Derived Normal), aliquot TCGA-GJ-A6C0-10A-01D-A30V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92bf870b-3d28-48b1-8841-f2da2c7867a8

The open-access MAF lists 56 somatic variants for this specimen: 39 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 33, Silent 17, Nonsense Mutation 3, Splice Region 1, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1265780497, COSV64672670; called by muse, mutect2, varscan2
- ADGRG1 | c.467G>C p.S156T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV65635448; called by muse, mutect2, varscan2
- ANKRD13B | c.1879T>C p.*627Qext*108 | Nonstop Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV61470578; called by muse, mutect2, varscan2
- ANXA10 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 40/364 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.282); catalogued as rs747923178, COSV63738673; called by muse, mutect2, varscan2
- ARHGEF10 | c.2465C>T p.S822F (on ENST00000398564; = p.S797F on NM_014629.4) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV50645796; called by muse, mutect2
- ARL14 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 12/214 reads (6%) | catalogued as COSV57899704; called by muse, mutect2
- BAZ2B | c.4592C>T p.T1531I | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.056); catalogued as COSV58598474; called by muse, mutect2
- C17orf75 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs1026176074; called by muse, mutect2
- C8B | c.1255A>G p.M419V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as COSV64777254; called by muse, mutect2, varscan2
- CLSTN3 | c.442C>G p.R148G | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.111); catalogued as COSV56935437, COSV56937934; called by muse, varscan2
- CYP1B1 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 10/192 reads (5%) | catalogued as COSV53191100; called by muse, mutect2
- EEF1G | c.533C>G p.P178R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV61321329; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1652T>G p.L551W | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57515429; called by muse, mutect2, varscan2
- FANCM | c.5152G>A p.V1718M | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs371629950; called by muse, mutect2, varscan2
- HEPACAM | c.389C>G p.T130S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as rs760592475, COSV100006005, COSV53429572; called by muse, mutect2, varscan2
- IL16 | c.3313T>G p.L1105V (on ENST00000302987 / NM_172217.5; = p.L404V on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57262204; called by muse, mutect2, varscan2
- IRX2 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1037197794, COSV57410611; called by muse, mutect2, varscan2
- ITGAD | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as COSV66757540; called by muse, mutect2, varscan2
- LAMA1 | c.5587A>T p.N1863Y | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as rs532071998, COSV67535034; called by muse, mutect2, varscan2
- LCE4A | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.979); catalogued as COSV59266542; called by muse, mutect2, varscan2
- LILRB1 | c.1885C>T p.P629S (on ENST00000427581; = p.P578S on NM_006669.6) | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV61116644, COSV61119102; called by muse, mutect2
- LRCH2 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 18/620 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100406353; called by muse, mutect2
- MAIP1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV54460434; called by muse, mutect2
- NCKAP5L | c.3586C>T p.P1196S | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as COSV60128736; called by muse, mutect2, varscan2
- NIPBL | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.037); catalogued as rs1554015273, COSV104390913, COSV56948569; ClinVar: uncertain significance; called by mutect2, varscan2
- NUP93 | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.137); catalogued as COSV57430002; called by muse, mutect2, varscan2
- OMP | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV53687017; called by mutect2, varscan2
- PDCD7 | c.1379G>A p.G460D | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV52600156; called by muse, mutect2, varscan2
- PHACTR3 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV63026684; called by mutect2, varscan2
- PRKDC | c.9339T>C p.N3113= | Splice Region (SNP) | VAF 20/90 reads (22%) | catalogued as COSV58048947; called by muse, mutect2, varscan2
- RAPGEF5 | c.650T>A p.L217H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.144); catalogued as COSV59781043; called by muse, mutect2, varscan2
- SHROOM4 | c.980G>A p.C327Y | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV56787418; called by muse, mutect2, varscan2
- SLC16A6 | c.449T>C p.I150T | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV59176904; called by muse, mutect2, varscan2
- SLC45A3 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65654800; called by muse, mutect2
- STRN4 | c.1048C>G p.R350G | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54417688; called by muse, mutect2, varscan2
- TMEM30B | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV63133479; called by muse, mutect2, varscan2
- ZNF451 | c.3037G>A p.A1013T (on ENST00000370706 / NM_001031623.3; = p.A965T on NM_015555.2) | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100674667; called by muse, mutect2
- ZNF512B | c.2017G>A p.G673S | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV53868684; called by muse, mutect2, varscan2
- EI24 | c.974_975del p.P325Lfs*61 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, varscan2
- CELSR1 | c.6690C>T p.N2230= | Silent (SNP) | VAF 53/91 reads (58%) | catalogued as rs147425309; called by muse, mutect2, varscan2
- CHMP7 | c.225G>A p.R75= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV57532695; called by muse, mutect2, varscan2
- CHST13 | c.279G>A p.P93= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs778742193, COSV60041812; called by muse, varscan2
- DDX19B | c.891G>A p.L297= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as rs1029934930, COSV55363568; called by muse, mutect2, varscan2
- DLST | c.564C>T p.P188= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV53165991; called by muse, mutect2
- EP300 | c.7131T>C p.A2377= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV54330470; called by muse, mutect2, varscan2
- FAM210A | c.818A>G p.*273= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV59183932; called by muse, mutect2, varscan2
- GLT1D1 | c.207G>A p.R69= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV55880301; called by muse, mutect2, varscan2
- MAGEE1 | c.60G>A p.A20= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV63909585; called by muse, varscan2
- MRGPRX3 | c.885G>T p.L295= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs768690835, COSV66933485; called by muse, mutect2, varscan2
- NOA1 | c.789G>A p.R263= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV51736530; called by muse, mutect2, varscan2
- OR6M1 | c.126C>A p.T42= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV58433252; called by muse, mutect2, varscan2
- PAPLN | c.2583C>T p.D861= (on ENST00000554301; = p.D834= on NM_173462.4) | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1183672453, COSV99389134; called by muse, mutect2
- PNMA8A | c.1215T>A p.P405= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV58136484; called by muse, mutect2, varscan2
- PRSS35 | c.819G>A p.L273= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV63800388; called by muse, mutect2, varscan2
- SLC9A8 | c.1257C>T p.I419= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV64287992; called by muse, mutect2, varscan2
- ZNF324B | c.990G>T p.R330= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV100351530; called by muse, mutect2, varscan2
